Somatic mutation profile of tumor specimen TCGA-J4-A67O-01A (aliquot TCGA-J4-A67O-01A-11D-A30E-08) from TCGA case TCGA-J4-A67O, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.4 years (21,714 days).
Specimen TCGA-J4-A67O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 394d758e-7629-47c7-bd1e-84e31fe09b41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-A67O-10A (Blood Derived Normal), aliquot TCGA-J4-A67O-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c9e3434-397a-44c9-8ff6-d195b04b5dbf

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 15, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.5045C>A p.T1682N | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100801794; called by muse, mutect2, varscan2
- FRMD3 | c.1482G>C p.L494F | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.724); catalogued as COSV58471568; called by muse, mutect2
- FRMD3 | c.1480T>G p.L494V | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.219); catalogued as COSV58471602; called by muse, mutect2
- L1CAM | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM064090, CM960913, COSV62830550; called by muse, mutect2, varscan2
- MGA | c.4877C>T p.T1626I | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.172); catalogued as COSV54964481; called by muse, mutect2
- NELFB | c.922C>T p.H308Y | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); catalogued as COSV58026689; called by muse, mutect2, varscan2
- NME8 | c.475A>C p.I159L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as rs763491394, COSV52256162; called by muse, mutect2
- OR6T1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs868745413, COSV58306274, COSV58307592; called by muse, mutect2
- RNF213 | c.10741G>A p.V3581I | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.073); catalogued as COSV60410521; called by muse, mutect2, varscan2
- SLC6A13 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV58261063; called by muse, mutect2
- TATDN1 | c.26T>C p.I9T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs767743512, COSV52679338; called by mutect2, varscan2
- TMF1 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs771029555, COSV68376091; called by muse, mutect2, varscan2
- ZAP70 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV53853651; called by muse, mutect2
- ZNF644 | c.209A>T p.N70I | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV61350766; called by muse, mutect2, varscan2
- CROCC | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CDC42BPB | c.3348C>A p.R1116= | Silent (SNP) | VAF 20/143 reads (14%) | catalogued as COSV63477206; called by muse, mutect2, varscan2
- KLHDC4 | c.324C>A p.T108= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV54511746; called by muse, mutect2, varscan2
- LRRC8C | c.381C>T p.F127= | Silent (SNP) | VAF 15/180 reads (8%) | catalogued as rs1185041573, COSV65002063; called by muse, mutect2
- NOS3 | c.1734T>C p.D578= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV52496722; called by muse, mutect2
- PANK1 | c.801G>C p.V267= (on ENST00000307534 / NM_148977.2; = p.V42= on NM_138316.4) | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV56811033; called by muse, mutect2, varscan2
